Somatic mutation profile of tumor specimen MP2PRT-PATAGU-TBP1-A (aliquot MP2PRT-PATAGU-TBP1-A-1-0-D-A81O-36) from MP2PRT case MP2PRT-PATAGU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.4 years (1,257 days).
Specimen MP2PRT-PATAGU-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 291d477d-9d4e-4c36-bac9-d0cd79c65f8b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATAGU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATAGU-NB1-A-1-0-D-A81O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3345f7a3-dbb3-43fb-9159-47336158358a

The open-access MAF lists 12 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 4, Frame Shift Ins 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 92/486 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANK3 | c.6355G>A p.D2119N | Missense Mutation (SNP) | VAF 78/442 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.284); catalogued as rs773857006, COSV55063020; called by muse, mutect2, varscan2
- SEZ6L | c.2600C>T p.S867L | Missense Mutation (SNP) | VAF 50/194 reads (26%) | SIFT tolerated (0.73); PolyPhen benign (0.424); catalogued as rs777971751, COSV50660091; called by muse, mutect2, varscan2
- UGT2B15 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 43/224 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as COSV57736709; called by muse, mutect2, varscan2
- ING3 | c.1065_1066insCCCC p.D356Pfs*5 | Frame Shift Ins (INS) | VAF 45/298 reads (15%) | called by mutect2, pindel, varscan2
- PREX2 | c.4216G>T p.V1406F | Missense Mutation (SNP) | VAF 33/204 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- ZBTB7B | c.1384delinsGG p.R462Gfs*58 (on ENST00000292176; = p.R496Gfs*58 on NM_001252406.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 155/837 reads (19%) | called by pindel, varscan2*
- DNAH17 | c.4719G>A p.T1573= | Silent (SNP) | VAF 51/414 reads (12%) | catalogued as rs779594093; called by muse, mutect2, varscan2
- NCBP3 | c.816A>G p.G272= | Silent (SNP) | VAF 41/180 reads (23%) | called by muse, mutect2, varscan2
- USH2A | c.12930C>T p.S4310= | Silent (SNP) | VAF 57/243 reads (23%) | called by muse, mutect2, varscan2
- VCX | c.78G>A p.P26= | Silent (SNP) | VAF 108/684 reads (16%) | catalogued as rs1284614035; called by muse, varscan2
- IRX5 | chr16:54929166 T>A | 5'Flank (SNP) | VAF 107/499 reads (21%) | catalogued as rs972381088; called by muse, mutect2, varscan2
